Surgical pathology report (de-identified scan), TCGA case TCGA-KN-8432, project TCGA-KICH (Kidney Chromophobe), tissue source site Harvard, specimen TCGA-KN-8432-01A (Primary Tumor).

[page 1 of 3]
Mass, kidney, right, radical nephrectomy:

Chromophobe renal cell carcinoma (11.5 cm), see synoptic report.

Kidney: Nephrectomy, Partial or Radical Synopsis

Staging according to American Joint Committee on Cancer Staging Manual -- 7th Edition.

MACROSCOPIC

Procedure: Radical nephrectomy.

Specimen Laterality: Right.

Tumor Site: Upper pole.

Tumor Focality: Unifocal.

Tumor Size: Greatest dimension: 11.5 cm. Additional dimensions: 9 cm x 9 cm.

Macroscopic Extent of Tumor:

Tumor limited to kidney.

MICROSCOPIC

Histologic Type: Chromophobe renal cell carcinoma.

[page 2 of 3]
Comatoid Features: Not identified.

Tumor Necrosis: *Not identified.

Histologic Grade: Not applicable.

Microscopic Tumor Extension:

- ✓ Tumor limited to kidney.

EXTENT OF INVASION (Pathologic Staging, pTMN)

Primary Tumor (pT): pT2b: Tumor more than 10 cm, limited to the kidney.

Regional Lymph Nodes (pN): pNX: Regional lymph nodes cannot be assessed.

Lymph Nodes: None submitted.

Distant metastasis (pM): Not applicable.

Margins:

Margins uninvolved by invasive carcinoma.

Adrenal Gland: Not present.

Lymph-Vascular Invasion (excluding renal vein and its muscle containing segmental branches and inferior vena cava): *Not identified.

Pathologic Findings in Nonneoplastic Kidney: None identified.

Clinical: Right renal mass.

Gross: The specimen is received fresh labeled with the patient's name [REDACTED] and additionally labeled "right kidney." The specimen consists of a kidney with attached perinephric adipose tissue that measures 14.5 x 10.5 x 5.5 cm with attached perinephric fat that measures 13 x 9 x 1.5 cm. The specimen weighs 613 grams. A segment of ureter is present and measures 14 cm in length and 0.4 cm in diameter. An adrenal gland is not present. The ureter is patent. The specimen is bivalved through the pelvic calyceal system. A tumor that measures 11.5 x 9 x 9 cm is present in the upper pole of the kidney. The cut surface of the tumor is solid, tan, brown and hemorrhagic. Tumor invasion into the perinephric adipose tissue and renal sinus is not identified. Invasion of the renal vein is not identified. No other lesions are noted within the renal parenchyma. The mucosa of the ureter and pelvis are unremarkable. The specimen is represented as follows: A=ureteral margin, B=vascular margin, C-D=representative sections of tumor with respect to kidney capsule, E=tumor with respect to pelvis, F-G=tumor with respect to unremarkable kidney, H=representative sections of unremarkable kidney, I-K=representative sections of sinus,

Source: NCI Genomic Data Commons file 0fd77934-c0c8-429f-a762-fdea27a2faaf (TCGA-KN-8432.6478555F-281D-458D-8E6F-82D22180512B.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).